Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3947, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3947-01A (Primary Tumor).

Diagnosis:

Resected ileocolic section with an ulcerated colon carcinoma characterized histologically as a moderately differentiated, partly mucinous rectal adenocarcinoma, located 3 cm aborally to Bauhin's valve, encircling the intestinal wall at a length of 12 cm. Invasive spread of the tumor within all intestinal walls up to the bordering subserous connective tissue and mesocolic fatty tissue. Continuing infiltration to an angular colon section adhering to the tumor. In addition, colon mucous membrane with five sessile serrated adenomas.

The tumor stage is therefore: pT4 pN0 (0/22) L0, V0; G2 R0.

Source: NCI Genomic Data Commons file d9c92f18-f740-450d-a73f-540c57410bbb (TCGA-AA-3947.B9614EB3-7A7F-4737-8E48-C13564EE1A4C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).